TCGA case TCGA-FY-A3I5 — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/52203ff5-57b2-4d56-8935-2ff1eb61d7b8

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Papillary carcinoma, follicular variant: ICD-O-3 morphology code: 8340/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 64.8 years (23,654 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Prior treatment: No; Residual disease: R0; Days to last follow up: 238 days; Tumor focality: Multifocal.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 14; Measurement unit: Centimeters; Tumor depth measurement: 3; Tumor length measurement: 4.5; Tumor width measurement: 3.

Follow-up (3 entries)
- Days to follow up: 50 days; Disease response: Tumor Free.
- Days to follow up: 238 days; Disease response: Tumor Free.
- Disease response: Complete Response; Timepoint: Within 3 Months of Surgery.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Hashimoto's Thyroiditis / Hypothyroidism.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FY-A3I5-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 210 mg.
  Slide TCGA-FY-A3I5-01B-01-TSA: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FY-A3I5-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FY-A3I5-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; History thyroid disease other: Hashimoto's Thyroiditis & Hypothyroidism; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Follicular (>= 99% follicular patterned); Laterality: Right lobe; Lymph nodes examined: Yes; New tumor event diagnosis indicator: No.
- Neoplasm dimension: Tumor size width: 3.0.
- Follow-up form: Lost to follow-up: Yes; Tumor status: Tumor free; Clinical status within 3 mths surgery: No imaging evidence of disease; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 238 days; disease-specific survival: no event (censored), 238 days; disease-free interval: no event (censored), 238 days; progression-free interval: no event (censored), 238 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FY-A3I5-01B-11D-A21Y-01): tumor purity 0.67, ploidy 2.58, whole-genome doublings 1.
